Somatic mutation profile of tumor specimen TCGA-3B-A9HX-01A (aliquot TCGA-3B-A9HX-01A-11D-A38Z-09) from TCGA case TCGA-3B-A9HX, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 70.2 years (25,627 days).
Specimen TCGA-3B-A9HX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c5810fb-af07-4d2d-90c6-50433223a71a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3B-A9HX-10A (Blood Derived Normal), aliquot TCGA-3B-A9HX-10A-01D-A38Z-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/822e02b2-3d47-4097-92fd-9b694c73e01a

The open-access MAF lists 42 somatic variants for this specimen: 32 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 27, Silent 10, Frame Shift Del 2, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACHE | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs768377541, COSV99574289; called by muse, mutect2, varscan2
- ALS2 | c.3394C>T p.R1132C | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs149670991, COSV51885571; called by muse, mutect2, varscan2
- AMER3 | c.737C>T p.S246L | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1401009215, COSV58465466; called by muse, mutect2, varscan2
- ARAP2 | c.3150G>T p.M1050I | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV100394930; called by muse, mutect2, varscan2
- ATRX | c.4766G>A p.G1589E | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100971149, COSV64882184; called by muse, mutect2, varscan2
- C2orf78 | c.2210G>A p.R737Q | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as rs1269480045, COSV68518313; called by muse, mutect2, varscan2
- CEL | c.1530C>G p.H510Q (on ENST00000673714; = p.H507Q on NM_001807.6) | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV100672467, COSV100672620; called by muse, mutect2, varscan2
- CNOT4 | c.2108A>T p.D703V (on ENST00000541284 / NM_001190850.1; = p.D629V on NM_013316.4) | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.776); catalogued as COSV100836167; called by muse, mutect2, varscan2
- CPZ | c.1830G>C p.L610F (on ENST00000360986 / NM_001014447.3; = p.L599F on NM_003652.3) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0.01); catalogued as rs778915613, COSV100249078, COSV100249323; called by muse, mutect2, varscan2
- HCCS | c.504G>T p.W168C | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100335742, COSV100335773; called by muse, mutect2, varscan2
- MESD | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV99930851; called by muse, mutect2, varscan2
- MOGAT3 | c.439G>A p.V147M | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as COSV99777230; called by muse, mutect2, varscan2
- MYCT1 | c.189C>G p.N63K | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.025); catalogued as COSV100924079, COSV100924102, COSV65890989; called by muse, mutect2, varscan2
- OBSCN | c.21874G>C p.A7292P | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100804734; called by muse, mutect2
- OR13C4 | c.938G>C p.R313T | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV99470232; called by muse, mutect2, varscan2
- PCDHB3 | c.1449C>G p.N483K | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50577009, COSV50579745, COSV99165782; called by muse, mutect2, varscan2
- POLG | c.2462T>G p.L821R | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99174924; called by muse, mutect2, varscan2
- PRIMPOL | c.874C>G p.L292V | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100153170; called by muse, mutect2, varscan2
- PRKG1 | c.16G>T p.E6* | Nonsense Mutation (SNP) | VAF 38/165 reads (23%) | catalogued as COSV100918026; called by muse, mutect2, varscan2
- RBBP7 | c.505G>T p.D169Y | Missense Mutation (SNP) | VAF 59/99 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV101198305; called by muse, mutect2, varscan2
- SLC12A3 | c.2206A>G p.N736D | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as COSV99344484; called by muse, mutect2, varscan2
- SLIT2 | c.3298T>C p.C1100R | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99885466; called by muse, mutect2, varscan2
- SULF1 | c.112C>T p.R38* | Nonsense Mutation (SNP) | VAF 38/98 reads (39%) | catalogued as rs1283840000, COSV52673785; called by muse, mutect2, varscan2
- THAP12 | c.1382A>G p.N461S | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99473111; called by muse, mutect2, varscan2
- TP53 | c.466C>G p.R156G | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.6); catalogued as CD156964, COSV52711846, COSV52730924, COSV53119766; called by muse, mutect2, varscan2
- VAC14 | c.224G>A p.G75D | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1160258220, COSV99934839; called by muse, mutect2, varscan2
- VMO1 | c.553G>A p.G185S | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs377200420, COSV99564787; called by muse, varscan2
- YARS1 | c.53T>G p.L18R | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100758375; called by muse, mutect2, varscan2
- ZNF804B | c.3250G>C p.G1084R | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.564); catalogued as COSV100304778, COSV100306221; called by muse, mutect2, varscan2
- DNMT3A | c.32_33insT p.T12Hfs*53 | Frame Shift Ins (INS) | VAF 14/72 reads (19%) | called by mutect2, varscan2
- DNMT3A | c.30_31del p.D11Hfs*53 | Frame Shift Del (DEL) | VAF 16/71 reads (23%) | called by mutect2, varscan2
- SVIL | c.1410del p.S472Lfs*11 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | called by mutect2, pindel, varscan2
- CFAP43 | c.3492T>C p.Y1164= | Silent (SNP) | VAF 9/99 reads (9%) | catalogued as COSV100829386; called by muse, mutect2
- GUCY2D | c.2937G>T p.L979= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV99644120; called by muse, varscan2
- MUC16 | c.42600C>T p.G14200= | Silent (SNP) | VAF 23/181 reads (13%) | catalogued as rs776151221, COSV66691668; called by muse, mutect2, varscan2
- NLGN4X | c.282G>A p.P94= | Silent (SNP) | VAF 29/52 reads (56%) | catalogued as rs777791438, COSV52011862, COSV52029785; ClinVar: likely benign; called by muse, mutect2, varscan2
- NPAP1 | c.690G>A p.A230= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as rs146878373; called by muse, mutect2, varscan2
- OBSL1 | c.2871G>T p.L957= | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as rs748851909, COSV99217142; called by muse, mutect2, varscan2
- OR13C4 | c.937A>C p.R313= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as COSV99470233, COSV99470340; called by muse, mutect2, varscan2
- RSL24D1 | c.228T>C p.N76= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs1204987371, COSV99548862; called by muse, mutect2, varscan2
- TMEM139 | c.399G>C p.G133= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as rs1415559445, COSV100131138; called by muse, mutect2, varscan2
- ZNF658 | c.2463A>G p.T821= | Silent (SNP) | VAF 101/257 reads (39%) | catalogued as rs551555151; called by muse, mutect2, varscan2
